Gene-level copy-number profile of tumor specimen TCGA-2G-AAF7-01A from TCGA case TCGA-2G-AAF7, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 30.3 years (11,065 days).
Specimen TCGA-2G-AAF7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 053a1a04-28e8-4254-9778-8235ee0c82db.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAF7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,878 have no estimate.
https://portal.gdc.cancer.gov/files/c3262adb-f41c-4893-9e90-398cdc44be90

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 2,752; copy number 2: 17,357; copy number 3: 30,051; copy number 4: 7,479; copy number 5: 294; copy number 6: 128; copy number 7: 65; copy number 8: 223; copy number 11: 13; copy number 12: 21; copy number 13: 98; copy number 14: 14; copy number 15: 5; copy number 16: 48; copy number 19: 25; copy number 25: 9; copy number 26: 23; copy number 27: 1; copy number 28: 23; copy number 29: 8; copy number 31: 13; copy number 43: 11; copy number 63: 37; copy number 67: 12.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:69,560,191–71,093,193, 29 genes: GTF2H2C, NAIPP3, AC139495.2, GUSBP3, AC139495.1, GUSBP13, AC131392.1, CDH12P2, SERF1B, SMN2, AC140134.1, NAIPP2, CDH12P3, AC138866.1, GUSBP14, GTF2H2B, AC146944.2, NAIPP1, AC146944.1, GUSBP15, GUSBP16, AC139272.1, CDH12P1, SERF1A, SMN1, AC139834.1, NAIP, GTF2H2, OCLNP1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 649 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:54,229,280–61,153,962, 96 genes, copy number 11–19 (within-gene range 4–19) (broad region; genes not listed).
- chr9:17,906,563–21,240,005, 58 genes, copy number 7–8: ADAMTSL1, AL442638.1, MIR3152, RN7SKP258, RAP1BP1, SAXO1, AL356000.1, RRAGA, HAUS6, SCARNA8, RNU6-264P, Y_RNA, PLIN2, AL161909.1, DENND4C, AL161909.2, AL391834.1, AL391834.2, RPS6, NDUFA5P3, ACER2, AL158206.1, MAP1LC3BP1, SLC24A2, C11orf98P1, AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3, AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14.
- chr9:28,863,626–28,888,955, 2 genes, copy number 7: MIR876, MIR873.
- chr12:3,791,047–5,032,941, 31 genes, copy number 7: PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1, GALNT8, AC005833.2, KCNA6, AC006063.1, AC005906.2, KCNA1, AC005906.1.
- chr12:9,852,984–32,756,463, 462 genes, copy number 7–67 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,566. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
